Somatic mutation profile of tumor specimen TCGA-B0-4710-01A (aliquot TCGA-B0-4710-01A-01D-1501-10) from TCGA case TCGA-B0-4710, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.0 years (27,396 days).
Specimen TCGA-B0-4710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32bfcc78-8aaf-4e32-b140-ce6193ab5664.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4710-11A (Solid Tissue Normal), aliquot TCGA-B0-4710-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1d342b0-7499-421e-92c6-97fac682f7b0

The open-access MAF lists 83 somatic variants for this specimen: 69 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 13, Frame Shift Del 8, Frame Shift Ins 4, Splice Region 2, Intron 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 98/404 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ACVR1C | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 191/520 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV54644784; called by muse, mutect2, varscan2
- AHNAK2 | c.1714G>A p.G572S | Missense Mutation (SNP) | VAF 142/644 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs765768380, COSV60911318; called by mutect2, varscan2
- ARMC3 | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53058891; called by muse, mutect2, varscan2
- ARMC6 | c.1111G>C p.E371Q (on ENST00000392336; = p.E346Q on NM_033415.4) | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV54180946; called by muse, mutect2, varscan2
- ASCC1 | c.748G>T p.A250S (on ENST00000342444 / NM_001369085.1; = p.A222S on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV57725850; called by muse, mutect2, varscan2
- CCDC42 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53448394; called by muse, mutect2, varscan2
- CCNE1 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV52903896; called by muse, mutect2, varscan2
- CCNE1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as rs578227778, COSV52903903; called by muse, mutect2, varscan2
- CHRD | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as COSV52606537; called by muse, mutect2
- DDOST | c.1147G>A p.D383N (on ENST00000415136; = p.D366N on NM_005216.5) | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs886045864, COSV58630785; ClinVar: uncertain significance; called by muse, mutect2
- DNAH17 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67751459; called by muse, mutect2, varscan2
- ECPAS | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as COSV52194123; called by mutect2, varscan2
- EFTUD2 | c.1960A>G p.K654E | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68182659; called by muse, mutect2, varscan2
- F8 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV64271085; called by muse, mutect2, varscan2
- FAM120A | c.2421C>G p.F807L | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV52902936; called by muse, mutect2, varscan2
- FAM200A | c.1444T>G p.S482A | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV68808617; called by muse, mutect2
- FAM200A | c.1442G>A p.S481N | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV68808620; called by muse, mutect2
- FCAR | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs143972917; called by muse, mutect2, varscan2
- FMN2 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as COSV60424164; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1368T>A p.T456= | Splice Region (SNP) | VAF 90/211 reads (43%) | catalogued as COSV58549531; called by muse, mutect2, varscan2
- GABRE | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64819200; called by muse, mutect2
- HECTD3 | c.1933C>A p.L645M | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV64669850; called by muse, mutect2, varscan2
- JAG2 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV59307710; called by muse, mutect2
- KBTBD8 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55127628; called by muse, varscan2
- MAGEA10 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.792); catalogued as COSV54883467; called by muse, mutect2, varscan2
- MAGEC1 | c.3080G>C p.G1027A | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53570089, COSV53580321; called by muse, varscan2
- MAOA | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 270/788 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV58642013; called by muse, mutect2, varscan2
- MBLAC2 | c.704T>G p.F235C | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57301889; called by muse, mutect2, varscan2
- MGAT4A | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 219/668 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53846123; called by muse, varscan2
- MOGAT2 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV52218811; called by muse, mutect2, varscan2
- NLRP5 | c.2813C>T p.T938M | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV66763167; called by muse, mutect2, varscan2
- OR5T3 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 139/411 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57379915; called by muse, mutect2, varscan2
- PABPC5 | c.884A>C p.E295A | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV57039729; called by muse, mutect2, varscan2
- PEX1 | c.1682C>G p.S561C | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV50394805, COSV50395561; called by muse, mutect2, varscan2
- PLCB4 | c.1552A>C p.N518H | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs758378211, COSV53796933; called by muse, mutect2, varscan2
- PLEKHA5 | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1203033795, COSV54696959; called by muse, mutect2, varscan2
- POGZ | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs867206997, COSV55033763; called by muse, mutect2, varscan2
- PRLR | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 141/405 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51494145; called by muse, mutect2, varscan2
- RPA4 | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 106/292 reads (36%) | catalogued as COSV61263930; called by muse, mutect2, varscan2
- SCN9A | c.5606C>A p.S1869Y (on ENST00000303354; = p.S1858Y on NM_002977.3) | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV57604533, COSV57613157; called by muse, mutect2, varscan2
- SCO1 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV55135107; called by muse, mutect2, varscan2
- SETD2 | c.4918T>A p.W1640R | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57433720; called by muse, mutect2, varscan2
- SI | c.41T>G p.I14S | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as COSV52271299; called by muse, mutect2
- SUGCT | c.1256A>G p.D419G (on ENST00000335693 / NM_001193313.2; = p.D445G on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59321499; called by muse, mutect2, varscan2
- TCERG1 | c.1663A>G p.M555V | Missense Mutation (SNP) | VAF 30/686 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.132); catalogued as rs746311634, COSV57035714; called by muse, mutect2
- TCP11 | c.1278T>A p.I426= (on ENST00000512012; = p.I364= on NM_018679.5) | Splice Region (SNP) | VAF 309/800 reads (39%) | catalogued as COSV55132768; called by muse, mutect2, varscan2
- TRHDE | c.2290C>A p.L764I | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV53838033; called by muse, mutect2, varscan2
- TRIM24 | c.2596A>C p.I866L (on ENST00000343526 / NM_015905.3; = p.I832L on NM_003852.4) | Missense Mutation (SNP) | VAF 168/576 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.127); catalogued as COSV58970533; called by muse, mutect2, varscan2
- UPK3B | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as rs764421327, COSV56859772; called by muse, mutect2, varscan2
- YY1AP1 | c.710T>C p.M237T (on ENST00000295566 / NM_139118.2; = p.M160T on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/451 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV55119952; called by muse, mutect2, varscan2
- ZMYM3 | c.2269C>A p.Q757K | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.333); catalogued as COSV58736881; called by muse, mutect2, varscan2
- ZNF22 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53585235; called by mutect2, varscan2
- ZNF607 | c.1511del p.P504Lfs*21 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | catalogued as COSV67696537; called by mutect2, pindel, varscan2
- ZYG11B | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 138/608 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53751266; called by muse, mutect2, varscan2
- ABCA13 | c.6700dup p.I2234Nfs*6 | Frame Shift Ins (INS) | VAF 41/114 reads (36%) | called by mutect2, pindel, varscan2
- ARL15 | c.445del p.A149Lfs*35 | Frame Shift Del (DEL) | VAF 46/171 reads (27%) | called by mutect2, pindel*, varscan2*
- BRF1 | c.1604_1617del p.S535Lfs*2 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- CHST1 | c.819del p.T274Rfs*37 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- CLNS1A | c.18_20del p.F7del | In Frame Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- DCAF11 | c.1371_1372dup p.S458Tfs*15 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel
- DDX6 | c.626dup p.M210Nfs*4 | Frame Shift Ins (INS) | VAF 197/676 reads (29%) | called by mutect2, pindel, varscan2
- GPSM1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MYO19 | c.2090C>A p.P697Q (on ENST00000614623 / NM_001163735.1; = p.P497Q on NM_025109.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYT1L | c.523del p.C175Vfs*6 | Frame Shift Del (DEL) | VAF 61/210 reads (29%) | called by mutect2, pindel, varscan2
- NPHP1 | c.929del p.P310Lfs*5 (on ENST00000393272 / NM_207181.4; = p.P310Lfs*6 on NM_000272.5) | Frame Shift Del (DEL) | VAF 55/197 reads (28%) | called by mutect2, pindel, varscan2
- NR6A1 | c.974del p.Q325Rfs*3 (on ENST00000487099 / NM_033334.4; = p.Q320Rfs*3 on NM_001489.5) | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel
- TRIP12 | c.2008dup p.M670Nfs*46 | Frame Shift Ins (INS) | VAF 96/339 reads (28%) | called by mutect2, pindel, varscan2
- ULK3 | c.240del p.Q81Sfs*41 | Frame Shift Del (DEL) | VAF 66/181 reads (36%) | called by mutect2, pindel, varscan2
- ARMCX2 | c.123C>T p.P41= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as COSV100168206, COSV57529566; called by muse, mutect2, varscan2
- ATP12A | c.1146C>T p.L382= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs778320466, COSV54514126; called by muse, mutect2, varscan2
- CALML5 | c.378C>T p.A126= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1321519946, COSV100981203; called by muse, varscan2
- CDH23 | c.1866C>T p.S622= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as rs397517312, COSV54928372; ClinVar: likely benign; called by muse, mutect2
- GPR27 | c.819G>T p.L273= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV55203464; called by muse, varscan2
- GSTA3 | c.333A>G p.L111= | Silent (SNP) | VAF 65/393 reads (17%) | catalogued as rs1413517735, COSV52980198; called by muse, mutect2, varscan2
- IFI30 | c.369G>A p.E123= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as rs1476067787, COSV55847269; called by muse, mutect2, varscan2
- MTNR1B | c.519G>C p.L173= | Silent (SNP) | VAF 67/189 reads (35%) | catalogued as COSV57065841; called by muse, mutect2, varscan2
- MYH14 | c.5862C>G p.T1954= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV51813312; called by muse, mutect2, varscan2
- TTC24 | c.954C>T p.S318= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV63997396; called by muse, mutect2, varscan2
- USH2A | c.6321C>A p.V2107= | Silent (SNP) | VAF 46/279 reads (16%) | catalogued as rs1165894782, COSV56346782; called by muse, mutect2, varscan2
- WDR18 | c.1245C>T p.I415= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV52121325; called by muse, mutect2, varscan2
- ZNF221 | c.964A>C p.R322= | Silent (SNP) | VAF 136/365 reads (37%) | catalogued as COSV52108703; called by muse, mutect2, varscan2
- NSD3 | c.1855+913G>T | Intron (SNP) | VAF 36/142 reads (25%) | catalogued as COSV100388679; called by muse, mutect2, varscan2
